TARGET case TARGET-15-SJMPAL044948 — Acute Lymphoblastic Leukemia - Phase III (TARGET-ALL-P3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Lymphoid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/c1f84e5f-9f6e-47e7-bc53-1cdc52048330

Demographics
Sex at birth: male; Age at index: 1 years; Vital status: Alive.

Diagnoses (1)
1. Acute lymphocytic leukemia: ICD-O-3 morphology code: 9835/3; ICD-10 code: C91.0; Tissue or organ of origin: Bone marrow; Classification of tumor: primary; Age at diagnosis: 1.5 years (547 days); Year of diagnosis: 2007; Days to last follow up: 3,439 days (9.4 years).

Follow-up (1 entry)
- Days to follow up: 3,439 days (9.4 years); Event-free: no event (relapse, second malignancy or death) recorded through day 3,439; Year of follow up: 2016.

Molecular and laboratory tests (laboratory values one line per visit day)
- Day 0: Leukocytes 217 ×10³/µL.

Biospecimens (1 sample)
- Sample TARGET-15-SJMPAL044948-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_ALL_ClinicalData_Phase_III_20230725.xlsx:
- Overall Survival Time in Days: 3439
- Protocol: Singapore
- WBC at Diagnosis: 217
- Initial Therapy: ALL
- Karyotype: 46,XY,dic(5;6)(q13;q21),der(7),t(5;7)(q22;p12),+21[22]
- WHO ALAL Classification: T/M
- WHO Dx: T/M
